Surgical pathology report (de-identified scan), TCGA case TCGA-BR-8690, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-8690-01A (Primary Tumor).

[page 1 of 3]
[REDACTED]

[REDACTED]	Case ID	Gross Description	Microscopic Description	Diagnosis Details
[REDACTED]	[REDACTED]	Lower third of the esophagus and a part of the stomach with ulcer-like tumor up to 5.5x4 cm in size in the cardial region. Invasion into the fatty tissue. In the fatty tissue there are hyperemic lymph nodes. Great omentum and surgical margins are of normal structure.	Adenocarcinoma of the stomach, G-2, with invasion into the perigastric fat and esophagus wall. Ten examined lymph nodes demonstrated metastases. Omentum is hyperemic. Surgical margins are free of tumor growth.	Tumor Features: Ulcerated, Tumor Extent: Perigastric fat , Venous Invasion: Absent, Margins: Absent, Treatment Effect:

[page 2 of 3]
Comments	Formatted Path Report
Original records read N2, but 10 positive lymph nodes are referred as N3a, according to the 7th edition of the TNM-classification.	STOMACH TISSUE CHECKLIST Specimen type: Subtotal gastrectomy Tumor site: Cardia Tumor size: 4 x 0 x 5.5 cm Tumor features: Ulcerated Histologic type: Adenocarcinoma Histologic grade: Moderately differentiated Tumor extent: Subserosa Lymph nodes: 10/10 positive for metastasis (Greater and lesser omentum 10/10) Lymphatic invasion: Not specified Venous invasion: Absent Perineural invasion: Not specified Margins: Uninvolved Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: None

ica ID

[page 3 of 3]
Excision date

--

Source: NCI Genomic Data Commons file 4224239f-3dc4-49be-b751-79267506588c (TCGA-BR-8690.F3E14A43-5309-4015-8115-897ADE3C3DE5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).